Somatic mutation profile of tumor specimen TCGA-D1-A17A-01A (aliquot TCGA-D1-A17A-01A-11D-A12J-09) from TCGA case TCGA-D1-A17A, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 59.0 years (21,560 days).
Specimen TCGA-D1-A17A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 242552f9-6a90-46ed-a585-f672056db08e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A17A-10A (Blood Derived Normal), aliquot TCGA-D1-A17A-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/313300e5-5d29-45d7-bc97-bf05f91ab144

The open-access MAF lists 275 somatic variants for this specimen: 207 protein-altering or splice-affecting, 59 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 59, Frame Shift Del 39, Nonsense Mutation 10, Frame Shift Ins 8, Splice Site 6, Intron 5, RNA 3, Nonstop Mutation 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 111/371 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 48/130 reads (37%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- LIFR | c.1578del p.K526Nfs*4 | Frame Shift Del (DEL) | VAF 42/153 reads (27%) | catalogued as rs1554020702; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 39/146 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 85/289 reads (29%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 51/161 reads (32%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ZBTB18 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 24/137 reads (18%) | catalogued as rs1064792999, CM162492, COSV62396102; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 44/132 reads (33%) | catalogued as rs749943218; called by mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 27/118 reads (23%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ADCY10 | c.3196A>G p.I1066V | Missense Mutation (SNP) | VAF 58/300 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV63243780; called by muse, mutect2, varscan2
- ADGRA2 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1471690899, COSV59446352; called by muse, mutect2, varscan2
- AKAP3 | c.1623G>T p.Q541H | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57419417; called by muse, mutect2, varscan2
- AKR1C2 | c.944dup p.N316* | Frame Shift Ins (INS) | VAF 66/224 reads (29%) | catalogued as rs782634158; called by mutect2, varscan2
- ANGPTL8 | c.30G>T p.W10C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52949466; called by muse, mutect2, varscan2
- ANKAR | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55616505; called by muse, mutect2, varscan2
- ARID1A | c.1627C>T p.Q543* | Nonsense Mutation (SNP) | VAF 211/583 reads (36%) | catalogued as COSV61372089, COSV61376935; called by muse, mutect2, varscan2
- ASB9 | c.868T>C p.F290L | Missense Mutation (SNP) | VAF 110/397 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66852188; called by muse, mutect2, varscan2
- AWAT2 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs180949354, COSV52144204; called by muse, mutect2, varscan2
- B4GALT4 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 25/209 reads (12%) | catalogued as rs772566300, COSV63296339; called by muse, mutect2, varscan2
- BMP2K | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 88/259 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770167074, COSV58594734, COSV58601109; called by muse, mutect2, varscan2
- BMPR2 | c.2593G>A p.D865N | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65812540; called by muse, mutect2, varscan2
- C16orf72 | c.56A>G p.H19R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.923); catalogued as COSV59916807; called by muse, mutect2, varscan2
- C1QC | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.438); catalogued as COSV65889986; called by muse, mutect2, varscan2
- C1RL | c.1381G>T p.G461W | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56926315; called by muse, mutect2, varscan2
- C5AR1 | c.943C>A p.L315I | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.23); catalogued as COSV61893103; called by muse, mutect2, varscan2
- C8orf34 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57409594; called by muse, mutect2, varscan2
- CA10 | c.506T>A p.V169D | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as COSV53364684; called by muse, mutect2, varscan2
- CAST | c.527C>T p.T176M (on ENST00000341926; = p.T259M on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as rs779432064, COSV57784671; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 54/193 reads (28%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CDON | c.635T>C p.V212A | Missense Mutation (SNP) | VAF 95/312 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV55000968; called by muse, mutect2, varscan2
- CELSR1 | c.3184C>A p.L1062M | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV53096904; called by muse, mutect2, varscan2
- CLIP1 | c.1942G>T p.G648W (on ENST00000620786 / NM_001247997.1; = p.G637W on NM_002956.2) | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56801325; called by muse, mutect2, varscan2
- CNDP2 | c.1297A>G p.M433V | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV60841093; called by muse, mutect2
- COL11A1 | c.1635del p.P546Lfs*87 | Frame Shift Del (DEL) | VAF 37/119 reads (31%) | catalogued as COSV100615079, COSV62186140; called by mutect2, pindel, varscan2
- COL15A1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.131); catalogued as rs374984385; called by muse, mutect2, varscan2
- CROCC | c.2692G>T p.E898* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV65014243; called by muse, mutect2, varscan2
- CSK | c.383A>G p.H128R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54975366; called by muse, mutect2, varscan2
- CYP4F12 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs199948303, COSV100216079, COSV61173608; called by muse, mutect2, varscan2
- DMBX1 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.999); catalogued as rs181379491; called by muse, mutect2, varscan2
- DMD | c.7081G>C p.G2361R | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.462); catalogued as COSV58939388, COSV58952677; called by muse, mutect2
- DNAJC9 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV54353734; called by muse, mutect2
- DNM1 | c.385+1G>A p.X129_splice | Splice Site (SNP) | VAF 16/41 reads (39%) | catalogued as COSV57854996; called by muse, mutect2, varscan2
- DSP | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs752143388, COSV65794692; called by muse, mutect2, varscan2
- DSTN | c.388+2T>C p.X130_splice | Splice Site (SNP) | VAF 20/204 reads (10%) | catalogued as COSV55713849; called by muse, mutect2, varscan2
- DYNC1I2 | c.1016C>T p.T339I | Missense Mutation (SNP) | VAF 101/331 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV55528844; called by muse, mutect2, varscan2
- EGLN1 | c.1150T>C p.Y384H | Missense Mutation (SNP) | VAF 115/561 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV64150192; called by muse, mutect2, varscan2
- EHBP1L1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764167148, COSV57079108; called by muse, mutect2, varscan2
- EIF5B | c.1422A>C p.E474D | Missense Mutation (SNP) | VAF 90/252 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56815925; called by muse, mutect2, varscan2
- EPRS1 | c.3060del p.E1021Kfs*17 | Frame Shift Del (DEL) | VAF 59/320 reads (18%) | catalogued as rs1394740497; called by mutect2, pindel, varscan2
- EZHIP | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1557318783, COSV57957251; called by muse, mutect2, varscan2
- FAT3 | c.9746C>T p.T3249I | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.125); catalogued as COSV53157032; called by muse, mutect2, varscan2
- FCSK | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55373976, COSV99851117; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs769482947; called by mutect2, varscan2
- FMN2 | c.2197G>A p.V733I | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV60445938; called by muse, mutect2, varscan2
- FRMD4A | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV62268051; called by muse, mutect2
- FSCB | c.1680G>C p.Q560H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.964); catalogued as COSV61219217; called by muse, mutect2, varscan2
- GAB2 | c.1181C>T p.A394V (on ENST00000361507 / NM_080491.3; = p.A356V on NM_012296.3) | Missense Mutation (SNP) | VAF 188/641 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60870197; called by muse, mutect2, varscan2
- GATAD2A | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 93/256 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as rs1196989680, COSV53074193; called by muse, mutect2, varscan2
- GDF5 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs750345162, COSV65502930; called by muse, mutect2, varscan2
- GK | c.1403C>T p.A468V (on ENST00000427190 / NM_001205019.2; = p.A462V on NM_000167.6) | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as rs757334363, COSV66732494; called by muse, mutect2, varscan2
- GNG4 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 77/414 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs756924811, COSV64000170; called by muse, mutect2, varscan2
- GOLGA2 | c.2623G>T p.E875* | Nonsense Mutation (SNP) | VAF 96/278 reads (35%) | catalogued as COSV57848916, COSV57855001; called by muse, mutect2, varscan2
- GORAB | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 77/360 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.34); catalogued as rs757240482, COSV63027694; called by muse, mutect2, varscan2
- H4C4 | c.310T>C p.*104Rext*? | Nonstop Mutation (SNP) | VAF 35/140 reads (25%) | catalogued as rs1407296074, COSV61591591, COSV61591740; called by muse, mutect2
- HDLBP | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 109/348 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs745739712, COSV60494747; called by muse, mutect2, varscan2
- IDE | c.1706del p.L569Cfs*45 | Frame Shift Del (DEL) | VAF 38/114 reads (33%) | catalogued as rs771790236; called by mutect2, varscan2
- IGSF21 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1378720517, COSV52129911, COSV52131696; called by muse, mutect2
- INSL6 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs757105790, COSV67563043; called by muse, mutect2, varscan2
- KATNAL2 | c.1226C>T p.A409V (on ENST00000356157 / NM_001353899.1; = p.A337V on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55305471; called by muse, mutect2, varscan2
- KCNH3 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1305657101, COSV57792251; called by muse, mutect2, varscan2
- KIF14 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 70/471 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as COSV66263359; called by muse, mutect2, varscan2
- KIF4B | c.1543C>T p.H515Y | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs761710449, COSV70530821; called by muse, mutect2, varscan2
- KLHL20 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 128/612 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52944206; called by muse, mutect2, varscan2
- KLHL36 | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50721904; called by muse, mutect2, varscan2
- KLK5 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV60451248; called by muse, mutect2, varscan2
- KMT2B | c.7258A>C p.S2420R | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV55821336; called by muse, mutect2, varscan2
- LCE1B | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1257160123, COSV63980561; called by muse, mutect2, varscan2
- LHX4 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 100/461 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754434517, COSV55377388; called by muse, mutect2, varscan2
- LRFN5 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53270016; called by muse, mutect2, varscan2
- LRWD1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52961729; called by muse, mutect2, varscan2
- MAP10 | c.1942C>T p.R648C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1468167951, COSV69364569; called by muse, mutect2, varscan2
- MBD4 | c.939del p.E314Kfs*4 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | catalogued as rs558765093; called by mutect2, varscan2
- MCAM | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV50683282; called by muse, mutect2, varscan2
- MDM2 | c.1238G>A p.S413N | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as rs1347318671, COSV50701933; called by muse, mutect2, varscan2
- MEGF8 | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs1440854966, COSV52097109; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 35/116 reads (30%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MMP10 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 105/325 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs760626821, COSV54247225; called by muse, mutect2, varscan2
- MROH6 | c.1813G>T p.G605C | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV52798025; called by muse, mutect2, varscan2
- MRPL15 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.686); catalogued as COSV52638401; called by muse, mutect2, varscan2
- MTMR11 | c.1945G>A p.G649S (on ENST00000439741 / NM_001145862.2; = p.G577S on NM_181873.3) | Missense Mutation (SNP) | VAF 89/438 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs782701393, COSV54966523; called by muse, mutect2, varscan2
- MTMR8 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 151/488 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs367826729, COSV66395682; called by muse, mutect2, varscan2
- MYH7 | c.1911G>T p.K637N | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV62522421; called by muse, mutect2, varscan2
- MYO1D | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as COSV59020699; called by muse, mutect2, varscan2
- NAGPA | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 27/89 reads (30%) | PolyPhen benign (0); catalogued as rs199604440; called by muse, mutect2, varscan2
- NIPA2 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs1309007021, COSV57414135; called by muse, mutect2, varscan2
- NOS1 | c.3406-1G>A p.X1136_splice | Splice Site (SNP) | VAF 58/162 reads (36%) | catalogued as rs1203304700, COSV57607278; called by muse, mutect2, varscan2
- NPHS1 | c.712+1G>A p.X238_splice | Splice Site (SNP) | VAF 36/127 reads (28%) | catalogued as COSV62289465; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | catalogued as rs776154715; called by mutect2, varscan2
- NSF | c.2207_2209del p.E736del | In Frame Del (DEL) | VAF 65/229 reads (28%) | catalogued as rs1377046356; called by pindel, varscan2
- NUBPL | c.608-1G>T p.X203_splice | Splice Site (SNP) | VAF 58/206 reads (28%) | catalogued as COSV55273122; called by muse, mutect2, varscan2
- NUP93 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 98/285 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746856372, COSV57429686; called by muse, mutect2, varscan2
- OBSCN | c.9446G>A p.R3149Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.069); catalogued as rs769573419, COSV52812052; called by muse, mutect2, varscan2
- OR10A2 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs746159207, COSV56300141; called by muse, mutect2, varscan2
- OR10S1 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.483); catalogued as COSV73342771; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 60/290 reads (21%) | catalogued as rs761899382; called by mutect2, varscan2
- OR52K1 | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 103/330 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as COSV56904433; called by muse, mutect2, varscan2
- P2RY1 | c.539T>C p.V180A | Missense Mutation (SNP) | VAF 94/426 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV59310179; called by muse, mutect2, varscan2
- PAICS | c.1069T>G p.W357G | Missense Mutation (SNP) | VAF 108/323 reads (33%) | PolyPhen benign (0.439); catalogued as COSV51709711; called by muse, mutect2, varscan2
- PAPOLG | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.044); catalogued as rs749124361, COSV53181497; called by muse, mutect2, varscan2
- PARN | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 69/652 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.413); catalogued as rs760452316, COSV58363668, COSV58363883; called by muse, mutect2, varscan2
- PCDHB5 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV50662901; called by muse, mutect2
- PCSK6 | c.1549C>T p.Q517* | Nonsense Mutation (SNP) | VAF 32/82 reads (39%) | catalogued as COSV59343785; called by muse, mutect2, varscan2
- PECR | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV54735504; called by muse, mutect2, varscan2
- PGAP1 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs760904211, COSV61328595; called by muse, mutect2, varscan2
- PPP2R1B | c.113A>G p.Q38R | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV59537054; called by muse, mutect2, varscan2
- PRDM13 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65030509; called by muse, mutect2, varscan2
- PROZ | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs1385845447, COSV61440052; called by muse, mutect2, varscan2
- PRRG3 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.862); catalogued as rs1026297893, COSV64851416; called by muse, mutect2
- PTK6 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 7/98 reads (7%) | catalogued as rs1240448700, COSV53918032; called by muse, mutect2
- PUF60 | c.1028C>T p.A343V (on ENST00000526683 / NM_001362896.2; = p.A326V on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV57591834; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1559T>C p.L520S | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV52790467; called by muse, mutect2, varscan2
- RFX3 | c.1931A>G p.Q644R | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as COSV56522709; called by muse, mutect2, varscan2
- RGR | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63894914; called by muse, mutect2, varscan2
- RHOG | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV53466712; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 35/134 reads (26%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 59/147 reads (40%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPTOR | c.3232G>A p.G1078S | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.101); catalogued as rs371494149; called by muse, mutect2, varscan2
- RREB1 | c.3568A>G p.T1190A | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as rs1000837350, COSV58562927; called by muse, varscan2
- RTCB | c.736dup p.M246Nfs*6 | Frame Shift Ins (INS) | VAF 108/336 reads (32%) | catalogued as rs771992011; called by mutect2, varscan2
- S1PR5 | c.830G>A p.C277Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs763804506, COSV61014391; called by muse, mutect2
- SCMH1 | c.1838C>T p.A613V (on ENST00000326197 / NM_001031694.2; = p.A544V on NM_012236.4) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV58238460; called by muse, mutect2, varscan2
- SCN10A | c.5028del p.Y1677Tfs*21 | Frame Shift Del (DEL) | VAF 24/276 reads (9%) | catalogued as rs748973626, COSV101479403; called by mutect2, pindel
- SERPINB13 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV54030411; called by muse, mutect2, varscan2
- SETX | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763545230, COSV56387265; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3GLB1 | c.201G>C p.L67F | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65280686; called by muse, mutect2, varscan2
- SHANK2 | c.2533C>T p.R845* | Nonsense Mutation (SNP) | VAF 85/251 reads (34%) | catalogued as COSV53613563; called by muse, mutect2, varscan2
- SLC22A12 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs370100606, COSV60574449; called by muse, mutect2, varscan2
- SLC39A4 | c.779G>A p.S260N (on ENST00000301305 / NM_001374839.1; = p.S235N on NM_017767.3) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52780753; called by muse, mutect2, varscan2
- SMAD7 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50991374; called by muse, mutect2, varscan2
- SORCS1 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs377202317; called by muse, mutect2, varscan2
- SPAG1 | c.1493T>C p.L498P | Missense Mutation (SNP) | VAF 21/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750545271, COSV52562153; called by muse, mutect2
- SPEN | c.7991C>T p.P2664L | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1347933435, COSV65366183; called by muse, mutect2, varscan2
- SSX7 | c.93C>A p.Y31* | Nonsense Mutation (SNP) | VAF 163/556 reads (29%) | catalogued as COSV53341045; called by muse, mutect2, varscan2
- STAT5B | c.2180A>G p.D727G | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.455); catalogued as COSV53185195; called by muse, mutect2, varscan2
- STIL | c.970C>A p.P324T | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54552632; called by muse, mutect2, varscan2
- STIMATE-MUSTN1 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as COSV56574244; called by muse, mutect2, varscan2
- SUCLG2 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56210427; called by muse, mutect2, varscan2
- SVIL | c.1244G>T p.R415M | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.258); catalogued as COSV63446755; called by muse, mutect2, varscan2
- SYNE1 | c.3137C>T p.T1046I (on ENST00000367255 / NM_182961.4; = p.T1053I on NM_033071.3) | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV55065355; called by muse, mutect2
- TAF1 | c.3316C>T p.R1106W (on ENST00000373790 / NM_138923.4; = p.R1127W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/395 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52121893; called by muse, mutect2, varscan2
- TFAM | c.441del p.E148Sfs*2 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs544132101; called by mutect2, varscan2
- TH | c.1462G>A p.V488M (on ENST00000381178 / NM_199292.3; = p.V457M on NM_000360.4) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760675839, COSV51748085; called by muse, mutect2, varscan2
- THBS2 | c.2858C>T p.A953V | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.738); catalogued as COSV64681374; called by muse, mutect2, varscan2
- TK1 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV56746427; called by muse, varscan2
- TNFSF12 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as COSV53433687; called by muse, mutect2, varscan2
- TNN | c.1684G>A p.V562M | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs141893855, COSV53432891; called by muse, mutect2, varscan2
- TPR | c.1223A>G p.Q408R | Missense Mutation (SNP) | VAF 95/462 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV66603912; called by muse, mutect2, varscan2
- TRAM2 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 82/300 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as rs1160106138, COSV51732668; called by muse, mutect2, varscan2
- TRDMT1 | c.941T>C p.V314A | Missense Mutation (SNP) | VAF 88/265 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV58320372; called by muse, mutect2, varscan2
- TRIM32 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.057); catalogued as rs778138359, COSV57806870; called by muse, mutect2, varscan2
- TSFM | c.1022A>C p.E341A (on ENST00000323833 / NM_001172696.2; = p.E320A on NM_005726.6) | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV57683228; called by muse, mutect2, varscan2
- UBE4B | c.1004T>C p.V335A | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); catalogued as COSV53539262; called by muse, mutect2, varscan2
- UBXN11 | c.1235T>C p.L412P (on ENST00000374221 / NM_183008.2; = p.L379P on NM_145345.2) | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53331761; called by muse, mutect2, varscan2
- UMODL1 | c.3767G>A p.R1256Q (on ENST00000408910 / NM_001004416.2; = p.R1384Q on NM_173568.3) | Missense Mutation (SNP) | VAF 99/263 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs188624715, COSV68570626; called by muse, mutect2, varscan2
- UNC5D | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as rs572476421, COSV54823100; called by muse, mutect2, varscan2
- UNC80 | c.401del p.G134Vfs*100 | Frame Shift Del (DEL) | VAF 28/104 reads (27%) | catalogued as COSV55900684; called by mutect2, pindel, varscan2
- USP51 | c.1761A>C p.K587N | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101540689, COSV72351869; called by muse, mutect2, varscan2
- USP54 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758059396, COSV60446062; called by muse, mutect2
- UXT | c.43del p.E15Rfs*38 | Frame Shift Del (DEL) | VAF 40/141 reads (28%) | catalogued as COSV100243846, COSV100243923; called by mutect2, pindel, varscan2
- VPS13D | c.2890A>G p.M964V | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs369300065; called by muse, mutect2
- WDR1 | c.1480G>A p.D494N (on ENST00000382452; = p.D354N on NM_005112.5) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.357); catalogued as rs766851145, COSV66725921; called by muse, mutect2, varscan2
- WDR45 | c.940C>T p.R314C (on ENST00000376372 / NM_001029896.2; = p.R315C on NM_007075.3) | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs1307990056, COSV59876708; called by muse, mutect2, varscan2
- WDTC1 | c.868dup p.E290Gfs*7 | Frame Shift Ins (INS) | VAF 40/146 reads (27%) | catalogued as rs747972901; called by mutect2, varscan2
- WNK2 | c.3932G>A p.R1311K | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52949410, COSV52955580; called by muse, mutect2, varscan2
- ZBTB12 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV64994074; called by muse, mutect2, varscan2
- ZDHHC24 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs536081289, COSV60080860; called by muse, mutect2, varscan2
- ZNF418 | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.047); catalogued as COSV68676265; called by muse, mutect2, varscan2
- ZNF429 | c.3+2T>C p.X1_splice | Splice Site (SNP) | VAF 33/120 reads (28%) | catalogued as COSV61918081; called by muse, mutect2, varscan2
- ZNF462 | c.5657G>A p.R1886H | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs373911531; called by muse, mutect2, varscan2
- ZNF579 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as rs1356850195, COSV57638519; called by muse, mutect2, varscan2
- ZNF599 | c.662A>G p.H221R | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61397028; called by muse, mutect2, varscan2
- ZNF701 | c.497A>G p.Q166R (on ENST00000301093; = p.Q100R on NM_018260.3) | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs758737675, COSV56524850; called by muse, mutect2, varscan2
- ZNF711 | c.2079del p.K693Nfs*3 | Frame Shift Del (DEL) | VAF 56/200 reads (28%) | catalogued as rs1264060719; called by mutect2, pindel, varscan2
- ZSCAN9 | c.173T>C p.L58P | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52850692; called by muse, mutect2, varscan2
- ADSS2 | c.473dup p.N158Kfs*30 | Frame Shift Ins (INS) | VAF 74/360 reads (21%) | called by mutect2, pindel, varscan2
- ALPK3 | c.2304del p.K768Nfs*12 | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | called by mutect2, pindel, varscan2
- AMN1 | c.494del p.N165Tfs*20 | Frame Shift Del (DEL) | VAF 81/290 reads (28%) | called by mutect2, pindel, varscan2
- ARHGAP35 | c.2834dup p.N946Efs*11 | Frame Shift Ins (INS) | VAF 28/116 reads (24%) | called by mutect2, varscan2
- BOLA3 | c.128del p.K43Sfs*8 | Frame Shift Del (DEL) | VAF 96/334 reads (29%) | called by mutect2, pindel, varscan2
- C4orf17 | c.352del p.I118Lfs*13 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- CACNA1G | c.5885_5907del p.A1962Gfs*11 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- DHX36 | c.578del p.N193Mfs*25 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, varscan2
- GATAD2B | c.1198_1199del p.S400Cfs*3 | Frame Shift Del (DEL) | VAF 45/260 reads (17%) | called by pindel, varscan2
- KHSRP | c.1229del p.G410Afs*18 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, varscan2
- MARK4 | c.527del p.N176Ifs*7 | Frame Shift Del (DEL) | VAF 36/111 reads (32%) | called by mutect2, pindel, varscan2
- MSTN | c.9del p.K3Nfs*13 | Frame Shift Del (DEL) | VAF 21/105 reads (20%) | called by mutect2, pindel, varscan2
- MTREX | c.2195del p.L732Wfs*29 | Frame Shift Del (DEL) | VAF 123/432 reads (28%) | called by mutect2, pindel, varscan2
- NCSTN | c.309del p.F103Lfs*5 | Frame Shift Del (DEL) | VAF 72/430 reads (17%) | called by mutect2, pindel, varscan2
- PCDH1 | c.3081del p.K1028Nfs*7 | Frame Shift Del (DEL) | VAF 58/188 reads (31%) | called by mutect2, pindel, varscan2
- PLA2G3 | c.46dup p.V16Gfs*51 | Frame Shift Ins (INS) | VAF 9/20 reads (45%) | called by mutect2, varscan2
- PRRC2B | c.3914del p.P1305Hfs*161 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- SLC5A5 | c.649del p.R217Afs*45 | Frame Shift Del (DEL) | VAF 201/716 reads (28%) | called by mutect2, pindel, varscan2
- SLC9A7 | c.1456del p.S486Qfs*23 | Frame Shift Del (DEL) | VAF 132/534 reads (25%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.110_114dup p.P39Gfs*150 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- ZFP42 | c.375dup p.G126Rfs*17 | Frame Shift Ins (INS) | VAF 42/106 reads (40%) | called by mutect2, pindel, varscan2
- ABL2 | c.1098C>T p.Y366= (on ENST00000502732 / NM_007314.4; = p.Y351= on NM_005158.5) | Silent (SNP) | VAF 76/417 reads (18%) | catalogued as rs373461386; called by muse, varscan2
- ACE | c.2520G>A p.R840= | Silent (SNP) | VAF 40/147 reads (27%) | catalogued as rs1378906822, COSV52011664; called by muse, mutect2, varscan2
- ANGPTL1 | c.432G>A p.K144= | Silent (SNP) | VAF 282/473 reads (60%) | catalogued as COSV52367774; called by muse, mutect2, varscan2
- AR | c.978C>T p.G326= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV65958640; called by muse, mutect2, varscan2
- ARFGEF2 | c.1698C>T p.C566= | Silent (SNP) | VAF 99/352 reads (28%) | catalogued as COSV64214304; called by muse, mutect2, varscan2
- ATF6 | c.243T>C p.C81= | Silent (SNP) | VAF 82/385 reads (21%) | catalogued as rs138607905; called by muse, mutect2, varscan2
- BIRC6 | c.2574G>A p.S858= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs150163773; called by muse, mutect2, varscan2
- BRAP | c.882C>T p.R294= | Silent (SNP) | VAF 68/194 reads (35%) | catalogued as COSV59538132; called by muse, mutect2, varscan2
- BSN | c.4975A>C p.R1659= | Silent (SNP) | VAF 51/191 reads (27%) | catalogued as COSV56524995; called by muse, mutect2, varscan2
- BTBD7 | c.1176C>A p.I392= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV58289400; called by muse, mutect2, varscan2
- CCDC116 | c.747C>T p.S249= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV53038564; called by muse, mutect2, varscan2
- CCT2 | c.99C>T p.I33= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as rs780733349, COSV54741127; called by muse, mutect2, varscan2
- CEACAM16 | c.936C>T p.L312= | Silent (SNP) | VAF 60/218 reads (28%) | catalogued as rs775440282, COSV69188030; called by muse, mutect2, varscan2
- CELSR1 | c.2886C>T p.A962= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as rs771214806, COSV53097148; called by muse, mutect2, varscan2
- CHST12 | c.591C>T p.R197= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs761289366, COSV51677330; called by muse, mutect2
- CHST2 | c.1116G>A p.A372= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs770246299, COSV58885059; called by muse, mutect2, varscan2
- CSMD3 | c.4473T>C p.P1491= (on ENST00000297405 / NM_001363185.1; = p.P1387= on NM_052900.3) | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV52276849; called by muse, mutect2
- CTDSP2 | c.606C>T p.D202= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV66080211; called by muse, mutect2, varscan2
- DNAH10 | c.13176T>C p.P4392= (on ENST00000409039; = p.P4331= on NM_207437.3) | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV53021514; called by muse, mutect2, varscan2
- ELFN2 | c.879G>A p.A293= | Silent (SNP) | VAF 82/318 reads (26%) | catalogued as rs761262814, COSV101297668, COSV68746015; called by muse, mutect2, varscan2
- ELL | c.1159C>A p.R387= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs35245196, COSV53214814; called by muse, mutect2, varscan2
- ENPP3 | c.114A>G p.G38= | Silent (SNP) | VAF 89/299 reads (30%) | catalogued as COSV62955779; called by muse, mutect2, varscan2
- EXOC3L2 | c.1449C>T p.G483= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as rs772308631, COSV52974165; called by muse, mutect2, varscan2
- FAM174B | c.348G>C p.S116= | Silent (SNP) | VAF 145/410 reads (35%) | catalogued as COSV100526666, COSV59264846; called by muse, mutect2, varscan2
- GAMT | c.234G>A p.V78= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV52040672; called by muse, mutect2, varscan2
- GPR39 | c.1035G>T p.T345= | Silent (SNP) | VAF 53/177 reads (30%) | catalogued as rs370162388, COSV61417310; called by muse, mutect2, varscan2
- HHIPL2 | c.1686T>C p.H562= | Silent (SNP) | VAF 102/541 reads (19%) | catalogued as COSV58566914; called by muse, mutect2, varscan2
- HKDC1 | c.1134C>T p.V378= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as COSV63578757; called by muse, mutect2
- IGKV1-8 | c.36G>T p.L12= | Silent (SNP) | VAF 116/412 reads (28%) | called by muse, mutect2, varscan2
- KCNC1 | c.339C>T p.R113= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV56394380; called by muse, mutect2, varscan2
- KCNC2 | c.1650G>A p.P550= | Silent (SNP) | VAF 136/429 reads (32%) | catalogued as rs200919813, COSV54376138; called by muse, mutect2, varscan2
- KIAA1755 | c.2019G>T p.A673= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV54079373, COSV99642511; called by muse, mutect2, varscan2
- MBTPS1 | c.381G>A p.T127= | Silent (SNP) | VAF 121/412 reads (29%) | catalogued as rs980416473, COSV58572034; called by muse, mutect2, varscan2
- MICAL1 | c.316C>T p.L106= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs369056262; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2061T>C p.S687= | Silent (SNP) | VAF 71/250 reads (28%) | catalogued as COSV56623269; called by muse, mutect2, varscan2
- NLGN1 | c.1521C>T p.D507= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as rs750939391, COSV64342999; called by muse, mutect2, varscan2
- NPSR1 | c.399C>T p.Y133= | Silent (SNP) | VAF 137/460 reads (30%) | catalogued as rs143552245; called by muse, mutect2, varscan2
- PCDH15 | c.1011T>C p.F337= | Silent (SNP) | VAF 41/138 reads (30%) | catalogued as rs746863424, COSV57369215; called by muse, mutect2, varscan2
- PCDHB15 | c.1638G>A p.L546= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV51231849; called by muse, mutect2, varscan2
- PNCK | c.288C>T p.G96= (on ENST00000340888 / NM_001366975.1; = p.G179= on NM_001039582.3) | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as rs782039916, COSV61745031; called by muse, mutect2, varscan2
- PSCA | c.177G>A p.L59= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV56652629, COSV56653432; called by muse, mutect2, varscan2
- RMND5B | c.1002C>A p.S334= | Silent (SNP) | VAF 146/394 reads (37%) | catalogued as COSV51071236; called by muse, mutect2, varscan2
- RNF207 | c.228G>A p.P76= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs1407778273, COSV65008172; called by muse, mutect2
- RORC | c.516T>C p.C172= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV59091883; called by muse, mutect2, varscan2
- SCN10A | c.3828C>T p.G1276= | Silent (SNP) | VAF 55/170 reads (32%) | catalogued as rs375572917; called by muse, mutect2, varscan2
- SLC7A14 | c.1101C>T p.D367= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as rs751620264, COSV51587461; called by muse, mutect2, varscan2
- SRP72 | c.1440T>C p.D480= | Silent (SNP) | VAF 42/157 reads (27%) | catalogued as COSV61378867; called by muse, mutect2, varscan2
- STAMBP | c.615A>G p.L205= | Silent (SNP) | VAF 94/291 reads (32%) | catalogued as rs779523532, COSV59898107; called by muse, mutect2, varscan2
- STRN | c.168G>A p.L56= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV55751001; called by muse, mutect2, varscan2
- THBD | c.840C>T p.C280= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV65702990; called by muse, mutect2, varscan2
- TNRC6A | c.351G>A p.P117= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs748070015, COSV59368584; called by muse, varscan2
- TOP1MT | c.1662G>A p.T554= | Silent (SNP) | VAF 70/192 reads (36%) | catalogued as rs1040162705, COSV61319294; called by muse, mutect2, varscan2
- TSPO | c.438C>T p.F146= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs747473912, COSV53356908; called by muse, mutect2, varscan2
- TTBK2 | c.1221C>T p.S407= | Silent (SNP) | VAF 52/185 reads (28%) | catalogued as rs779352666, COSV51172436; called by muse, mutect2, varscan2
- UBTD1 | c.318C>T p.Y106= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs369006929; called by muse, mutect2, varscan2
- WNT5B | c.402C>T p.R134= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs1282804118, COSV60198562; called by muse, mutect2, varscan2
- YY2 | c.768C>T p.C256= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as rs781046792, COSV63412220; called by muse, mutect2, varscan2
- ZNF25 | c.1365G>A p.E455= | Silent (SNP) | VAF 57/205 reads (28%) | catalogued as COSV56923716; called by muse, mutect2, varscan2
- ZNF830 | c.204T>G p.T68= | Silent (SNP) | VAF 49/196 reads (25%) | catalogued as rs774889198, COSV58491086; called by muse, mutect2, varscan2
- ARHGEF11 | c.583-1744C>T | Intron (SNP) | VAF 66/340 reads (19%) | catalogued as rs747953086, COSV63814961; called by muse, mutect2, varscan2
- DCHS2 | n.7636C>T | RNA (SNP) | VAF 24/77 reads (31%) | catalogued as rs77468185, COSV61777606; called by muse, mutect2, varscan2
- MACF1 | c.15832-8635C>T | Intron (SNP) | VAF 19/68 reads (28%) | catalogued as rs371382486; called by muse, varscan2
- MROH8 | c.370+2463A>G | Intron (SNP) | VAF 138/430 reads (32%) | catalogued as COSV54123326; called by muse, mutect2, varscan2
- PPP2R1B | chr11:111737455 A>G | 3'Flank (SNP) | VAF 44/164 reads (27%) | catalogued as COSV59537050; called by muse, mutect2, varscan2
- PRR12 | c.51+400del | Intron (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- SSPOP | n.14168C>T | RNA (SNP) | VAF 5/16 reads (31%) | catalogued as rs759133003, COSV65135094; called by muse, mutect2
- SSPOP | n.14730dup | RNA (INS) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- UMODL1 | c.1520-1187del | Intron (DEL) | VAF 85/254 reads (33%) | called by mutect2, pindel, varscan2
